Gene-level copy-number profile of tumor specimen TCGA-IB-7654-01A from TCGA case TCGA-IB-7654, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.2 years (29,292 days).
Specimen TCGA-IB-7654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.9423b4b6-c0ca-482c-b071-4b77b0d15f31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-7654-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/fdfb2bd2-ff33-4065-a444-7e56da1e78bf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 7,737; copy number 2: 47,318; copy number 3: 3,071; copy number 4: 1,244; copy number 5: 75; copy number 6: 140; copy number 12: 17; copy number 14: 60; copy number 20: 10; copy number 22: 12; copy number 23: 33.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 347 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,713,880–41,484,683, 130 genes, copy number 6 (broad region; genes not listed).
- chr1:41,535,443–41,628,816, 3 genes, copy number 6: AL445933.2, AL445933.1, AC119676.1.
- chr12:164,664–5,406,651, 132 genes, copy number 12–23 (broad region; genes not listed).
- chr15:76,976,915–79,472,304, 75 genes, copy number 5 (broad region; genes not listed).
- chr18:29,256,817–30,714,286, 7 genes, copy number 6: AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F, AC090506.1.

Autosomal genes at a single copy (total copy number 1): 5,458. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
